Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZC-06A from TCGA case TCGA-FS-A1ZC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.7 years (29,093 days).
Specimen TCGA-FS-A1ZC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.604e094c-b0b5-4fb4-b9be-872c31ef8364.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b50c6ae4-b0a1-4ea9-afbf-ba86a764afb7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,426; copy number 2: 9,791; copy number 3: 31,799; copy number 4: 13,177; copy number 5: 1; copy number 6: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZC-06A-11D-A191-01): tumor purity 0.89, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:174,631,823–174,632,064, 1 gene: RN7SKP40.
- chr4:181,064,089–181,237,564, 2 genes (within-gene range 0–2): LINC00290, AC019235.1.
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr14:79,893,080–79,974,169, 1 gene (within-gene range 0–2): AF123462.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
